Gene-level copy-number profile of tumor specimen ALCH-AELX-TTP1-A from ALCHEMIST case ALCH-AELX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.9 years (25,527 days).
Specimen ALCH-AELX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d6d8b1fa-709a-4473-bd2e-cc8705fbd228.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AELX-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/aa950046-389d-4265-95ab-c4fe0fdfa312

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 1,213; copy number 2: 11,726; copy number 3: 22,049; copy number 4: 15,570; copy number 5: 5,348; copy number 6: 963; copy number 7: 175; copy number 8: 714; copy number 9: 114; copy number 10: 199; copy number 11: 2; copy number 12: 152; copy number 13: 69; copy number 14: 2; copy number 15: 35; copy number 16: 11; copy number 18: 24; copy number 24: 2.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:223,976,146–223,976,249, 1 gene: RNU6-1319P.
- chr4:119,405,523–119,454,638, 1 gene (within-gene range 0–2): GTF2IP12.
- chr4:119,434,005–119,434,108, 1 gene: RNU6-1217P.
- chr4:119,456,350–119,457,277, 1 gene (within-gene range 0–2): AC093752.2.
- chr9:61,190,003–61,642,494, 10 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA.
- chr9:61,665,579–61,666,386, 1 gene: AL935212.2.
- chr11:64,823,052–64,844,653, 1 gene: CDC42BPG.
- chr11:120,867,933–120,894,797, 1 gene (within-gene range 0–3): AP004147.1.
- chr15:21,293,653–21,295,201, 1 gene: AC068446.1.
- chr16:35,021,749–35,085,060, 5 genes (within-gene range 0–7): AC135776.1, AC135776.2, AC135776.3, CCNYL3, CLUHP11.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,498 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:196,867,856–196,987,558, 7 genes, copy number 7: SENP5, AC016949.1, NCBP2, NCBP2-AS1, NCBP2AS2, PIGZ, RPSAP69.
- chr3:197,042,560–197,299,330, 1 gene, copy number 7 (within-gene range 3–7): DLG1.
- chr5:58,198–21,589,372, 355 genes, copy number 8–14 (within-gene range 3–14) (broad region; genes not listed).
- chr5:24,749,374–25,445,925, 15 genes, copy number 8: AC091893.1, AC106821.2, BTG4P1, SNORD29, LINC02239, AC106821.1, Y_RNA, LINC02228, LINC02211, AC099499.2, AC099499.1, AC106754.1, AC106754.2, AC022140.1, AC022140.2.
- chr7:37,032–176,013, 7 genes, copy number 8: AC215522.1, AC093627.1, AC093627.6, AC093627.5, AC093627.4, AC093627.7, AC093627.2.
- chr7:6,835,420–7,293,880, 16 genes, copy number 7: OR7E39P, UNC93B2, OR7E136P, OR7E59P, AC079804.2, ALG1L5P, AC079804.1, FAM86LP, AC079804.3, MIR3683, AC092104.1, Y_RNA, C1GALT1, AC005532.2, AC005532.1, AC079448.1.
- chr7:12,726,152–13,751,920, 1 gene, copy number 7 (within-gene range 6–7): AC011287.1.
- chr7:13,339,201–13,365,049, 1 gene, copy number 7: AC011287.2.
- chr7:24,698,355–28,279,700, 92 genes, copy number 7 (broad region; genes not listed).
- chr7:44,512,535–45,088,969, 20 genes, copy number 7: NPC1L1, DDX56, TMED4, AC011894.1, OGDH, ZMIZ2, AC013436.1, PPIA, H2AZ2, LINC01952, PURB, MIR4657, AC004854.2, AC004854.1, AC004847.1, MYO1G, SNHG15, SNORA9, CCM2, NACAD.
- chr7:53,490,148–55,433,742, 28 genes, copy number 8–11 (within-gene range 8–12): RN7SKP218, AC009468.2, AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2.
- chr8:115,408,496–120,373,573, 52 genes, copy number 7–9: TRPS1, AF178030.1, LINC00536, RNA5SP276, AC090994.1, AC105177.1, EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD, SLC30A8, RN7SL228P, AC027419.1, AC027419.2, RN7SL826P, AC084114.1, AP002848.1, MED30, RPS10P16, EXT1, SAMD12, AC023590.1, SAMD12-AS1, RPS26P35, TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2, MAL2-AS1, MIR548AZ, AC021733.4, AC021733.1, CCN3, AC021733.2, AC021733.3, ENPP2, CYCSP23, RN7SKP153, TAF2, AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1, DEPTOR, RNA5SP277, AC091563.1, COL14A1.
- chr8:125,466,939–144,336,482, 299 genes, copy number 7–10 (broad region; genes not listed).
- chr9:64,637,845–64,765,535, 3 genes, copy number 13–16: AL445665.1, BMS1P11, IGKV1OR-2.
- chr9:65,219,987–65,285,209, 3 genes, copy number 10–24: AL512605.1, AL512605.2, FOXD4L5.
- chr13:101,053,776–114,337,626, 184 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).
- chr14:22,147,995–22,543,240, 88 genes, copy number 8 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 8: TRAC.
- chr14:30,874,514–31,457,441, 16 genes, copy number 15 (within-gene range 4–15): COCH, AL049830.3, STRN3, HIGD1AP17, MIR624, AL049830.4, AP4S1, HECTD1, RPL21P5, RNU6-541P, Y_RNA, AL136418.1, Y_RNA, HEATR5A, ATP5MC1P2, AL139353.1.
- chr14:50,237,563–50,944,483, 24 genes, copy number 18: L2HGDH, MIR4504, DMAC2L, AL359397.2, CDKL1, AL359397.1, MAP4K5, AL118556.1, Y_RNA, AL118556.2, ATL1, SNRPGP1, SAV1, RN7SL452P, AL606834.1, ZFP64P1, NIN, AL606834.2, AL133485.2, AL133485.1, AL358334.1, PYGL, ABHD12B, AL358334.3.
- chr14:55,229,217–60,323,907, 99 genes, copy number 9–16 (broad region; genes not listed).
- chr16:35,085,896–35,154,366, 6 genes, copy number 7: NAMPTP3, VPS35P1, VN1R68P, VN1R69P, AC023824.5, AC023824.6.
- chr19:16,355,239–16,472,085, 1 gene, copy number 8 (within-gene range 2–8): EPS15L1.
- chr19:16,412,684–18,896,727, 141 genes, copy number 8 (broad region; genes not listed).
- chr19:23,204,010–24,163,425, 38 genes, copy number 8: AC092329.2, ZNF724, AC092329.3, BNIP3P38, IPO5P1, AC092329.1, AC092329.4, VN1R90P, VN1R91P, ZNF91, AC010300.1, BNIP3P8, CDC42EP3P1, LINC01224, VN1R92P, AC074140.1, ZNF725P, ZNF675, AC073544.1, RPS27P29, VN1R93P, ZNF681, AC139769.1, BNIP3P39, AC139769.2, RPSAP58, AC139769.3, ZNF726, AC011503.1, AC011503.2, AC011503.3, RNA5-8SP4, AC092279.1, ZNF254, AC092279.2, BNIP3P40, AC073534.2, AC073534.1.

Autosomal genes at a single copy (total copy number 1): 1,210. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
